Somatic mutation profile of tumor specimen HTMCP-03-06-02104-01A (aliquot HTMCP-03-06-02104-01A-01D-5099) from CGCI case HTMCP-03-06-02104, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0509b27c-4399-45e7-a8a0-9f8c6c2f1938.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02104-10A (Blood Derived Normal), aliquot HTMCP-03-06-02104-10A-01D-5099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65898c0d-9ce0-4652-b8ec-7ea10128c55a

The open-access MAF lists 131 somatic variants for this specimen: 92 protein-altering or splice-affecting, 31 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 31, Nonsense Mutation 10, Intron 6, RNA 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB11 | c.3855C>G p.I1285M | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV99791531; called by muse, mutect2, varscan2
- ABCC10 | c.1645C>A p.L549I (on ENST00000372530 / NM_001198934.2; = p.L506I on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.192); catalogued as rs1420953999; called by muse, mutect2, varscan2
- ADAMTS6 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101125209, COSV66858879; called by muse, mutect2, varscan2
- AHNAK | c.10930G>C p.D3644H | Missense Mutation (SNP) | VAF 79/385 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1341592662; called by muse, mutect2, varscan2
- ALPK2 | c.5250G>T p.K1750N | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV64491095; called by muse, mutect2, varscan2
- ARHGEF6 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); catalogued as rs373225685, COSV51693516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP13A5 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149839711, COSV60868943; called by muse, mutect2, varscan2
- CAMSAP3 | c.3670G>A p.D1224N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50330915; called by muse, mutect2, varscan2
- DOCK9 | c.2443C>T p.H815Y (on ENST00000376460 / NM_001366676.2; = p.H816Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as COSV100237496; called by muse, mutect2, varscan2
- DPP10 | c.2191C>T p.H731Y | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59697538; called by muse, mutect2, varscan2
- ELOA2 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.651); catalogued as rs1462226643; called by muse, mutect2, varscan2
- EPB41L3 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV100550179; called by muse, mutect2, varscan2
- FLG | c.8936G>A p.G2979E | Missense Mutation (SNP) | VAF 64/540 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs765947651; called by muse, varscan2
- FLG | c.6769G>A p.E2257K | Missense Mutation (SNP) | VAF 74/430 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as COSV64247458; called by muse, varscan2
- FLG | c.6292G>A p.E2098K | Missense Mutation (SNP) | VAF 86/674 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.264); catalogued as rs1240887192, COSV64245851; called by muse, mutect2, varscan2
- FNIP1 | c.3319C>G p.L1107V | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100330333; called by muse, mutect2, varscan2
- GLG1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as rs745573951, COSV52664016, COSV99215873; called by muse, mutect2, varscan2
- GPHN | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV59475445; called by muse, mutect2, varscan2
- HDLBP | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV60496638; called by muse, mutect2, varscan2
- HLA-A | c.896-1G>C p.X299_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV65139440; called by muse, mutect2, varscan2
- HUWE1 | c.7981G>C p.E2661Q | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV53335778; called by muse, mutect2, varscan2
- IGHMBP2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs571887680, COSV54821303; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNB2 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); catalogued as rs757936160; called by muse, varscan2
- LRRC40 | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100918420, COSV63939046; called by muse, mutect2, varscan2
- MEFV | c.2110G>A p.V704I | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs104895096, CM012154, COSV54820562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP20 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1248480204, CM157167, COSV52776973; called by muse, mutect2, varscan2
- MS4A7 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759749560, COSV55732607; called by muse, mutect2, varscan2
- MYO9A | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758551241, COSV100614307; called by muse, mutect2, varscan2
- NRXN1 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as rs1285800435, COSV58459244, COSV58493099; called by muse, mutect2, varscan2
- NUP155 | c.254G>A p.R85Q (on ENST00000231498 / NM_153485.3; = p.R26Q on NM_004298.4) | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1216371996, COSV51535150; called by muse, mutect2, varscan2
- OR51E2 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143376710; called by muse, mutect2
- PALD1 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as rs749892676, COSV54974683; called by muse, mutect2, varscan2
- PCDH18 | c.3043C>T p.L1015F | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1388106859; called by muse, mutect2, varscan2
- PCDHB7 | c.1543G>T p.A515S | Missense Mutation (SNP) | VAF 31/388 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs1415657938; called by muse, mutect2
- PCDHGA11 | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV53895395; called by muse, mutect2, varscan2
- PCDHGA6 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); catalogued as rs749559180, COSV53894058; called by muse, mutect2, varscan2
- PCDHGB6 | c.2374C>A p.H792N | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs533810160; called by muse, mutect2
- PCNP | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as rs1413341461, COSV99504140; called by muse, mutect2, varscan2
- PEG3 | c.4407G>T p.E1469D | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV55645186; called by muse, mutect2, varscan2
- PRDM16 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.091); catalogued as rs61756438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKDC | c.6952G>A p.A2318T | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779732085, COSV100044110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMS2 | c.2117G>A p.R706H (on ENST00000666250 / NM_001348490.2; = p.R514H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs754256738, COSV51679147, COSV99154333; called by muse, mutect2
- RNF213 | c.7226G>A p.R2409Q | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745694603; called by muse, mutect2, varscan2
- SHLD1 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1568537141; called by muse, mutect2, varscan2
- SLC6A5 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54229339; called by muse, mutect2, varscan2
- TRHDE | c.1730G>T p.R577I | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV53835051, COSV99668350; called by muse, mutect2, varscan2
- TTC30A | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV63102226; called by muse, mutect2, varscan2
- XIRP2 | c.6469G>A p.E2157K (on ENST00000628543; = p.E2332K on NM_152381.6) | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.631); catalogued as rs1559042763, COSV54718438, COSV99745445; called by muse, mutect2, varscan2
- ZBTB20 | c.1099G>A p.E367K (on ENST00000474710 / NM_001164342.2; = p.E294K on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV61855977; called by muse, mutect2, varscan2
- ZFYVE28 | c.1916C>A p.S639* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99343880; called by muse, mutect2, varscan2
- ZNF775 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.925); catalogued as rs780551176; called by muse, mutect2, varscan2
- ABCA9 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ADAR | c.1095C>G p.I365M | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANGPTL3 | c.1196C>G p.S399* | Nonsense Mutation (SNP) | VAF 35/105 reads (33%) | called by muse, mutect2, varscan2
- ANKRD62 | c.1417C>T p.Q473* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- CCDC120 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP290 | c.6125C>G p.S2042C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by mutect2, varscan2
- CTTNBP2 | c.4519G>C p.E1507Q | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DNAH7 | c.5423C>A p.S1808Y | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- DOCK7 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- E2F7 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELL | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FSIP2 | c.10964G>A p.R3655K | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA6L6 | c.683T>C p.I228T | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- GPSM2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- GPSM2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HRNR | c.7953G>T p.Q2651H | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ITGA8 | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1109 | c.11510C>G p.S3837* | Nonsense Mutation (SNP) | VAF 36/120 reads (30%) | called by muse, mutect2, varscan2
- KIAA1841 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- KMT2E | c.2451G>T p.K817N | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUC17 | c.2891C>G p.S964C | Missense Mutation (SNP) | VAF 297/1544 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MYH9 | c.4042G>T p.E1348* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- MYO3B | c.2638C>G p.L880V | Missense Mutation (SNP) | VAF 95/267 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- NAA25 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- NBPF3 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- NHS | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OBSCN | c.12268C>T p.Q4090* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- PCDH12 | c.2020G>T p.E674* | Nonsense Mutation (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2, varscan2
- PTPRF | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RC3H2 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 95/253 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- REV3L | c.2801C>T p.S934L | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RSPH4A | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- RUVBL2 | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPATC1 | c.335C>A p.S112* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- SRCAP | c.1962C>G p.I654M | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM2 | c.2563G>A p.E855K (on ENST00000518659 / NM_001122679.2; = p.E623K on NM_001080428.3) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM7 | c.747G>C p.Q249H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2
- UPF2 | c.2596C>G p.Q866E | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF263 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZNF541 | c.3485C>G p.S1162* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- ADAMTSL4 | c.1794C>T p.V598= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- ALKBH8 | c.1752G>A p.R584= | Silent (SNP) | VAF 58/263 reads (22%) | called by muse, mutect2, varscan2
- AURKA | c.867C>T p.L289= | Silent (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- CALR | c.264C>T p.G88= | Silent (SNP) | VAF 16/440 reads (4%) | called by muse, mutect2
- CEP290 | c.3336G>A p.Q1112= | Silent (SNP) | VAF 60/235 reads (26%) | catalogued as rs1426235782, COSV58349495; called by muse, mutect2, varscan2
- CEP350 | c.5217C>T p.L1739= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV62606236; called by muse, mutect2, varscan2
- CHD4 | c.3297C>T p.F1099= (on ENST00000357008 / NM_001363606.2; = p.F1112= on NM_001273.5) | Silent (SNP) | VAF 75/169 reads (44%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.556C>A p.R186= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as COSV70480403; called by muse, mutect2, varscan2
- COL12A1 | c.5550G>C p.L1850= | Silent (SNP) | VAF 59/109 reads (54%) | catalogued as COSV100485789; called by muse, mutect2, varscan2
- CRKL | c.837G>C p.V279= | Silent (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- DMPK | c.789G>A p.A263= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs754630789, COSV52182566; called by muse, mutect2, varscan2
- EPHA6 | c.2082C>T p.F694= (on ENST00000389672 / NM_001080448.3; = p.F86= on NM_173655.4) | Silent (SNP) | VAF 35/159 reads (22%) | catalogued as COSV67572498; called by muse, mutect2, varscan2
- GNAI1 | c.681G>A p.L227= | Silent (SNP) | VAF 39/246 reads (16%) | called by muse, mutect2, varscan2
- IRS4 | c.750G>C p.L250= | Silent (SNP) | VAF 35/136 reads (26%) | called by muse, mutect2, varscan2
- LGI4 | c.1599C>T p.I533= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs138821361, COSV100032942; called by muse, mutect2, varscan2
- LRRN4 | c.1848G>C p.A616= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- LY75 | c.2287C>A p.R763= | Silent (SNP) | VAF 47/163 reads (29%) | called by muse, mutect2, varscan2
- MN1 | c.2994G>A p.P998= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV56560314; called by muse, mutect2, varscan2
- MTMR11 | c.381C>T p.I127= (on ENST00000439741 / NM_001145862.2; = p.I55= on NM_181873.3) | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs782104828; called by muse, mutect2, varscan2
- MYO15A | c.9807C>A p.L3269= | Silent (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- NAV1 | c.1125C>T p.V375= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs777453827; called by muse, mutect2, varscan2
- OR51D1 | c.504C>T p.F168= | Silent (SNP) | VAF 69/342 reads (20%) | catalogued as rs758247032; called by muse, mutect2, varscan2
- PCDHGB6 | c.1752C>T p.P584= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs774233531, COSV53904617; called by muse, mutect2, varscan2
- PCYOX1L | c.1317C>T p.L439= | Silent (SNP) | VAF 62/187 reads (33%) | called by muse, mutect2, varscan2
- PKP3 | c.2082G>A p.T694= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs560629668, COSV100230146; called by muse, mutect2, varscan2
- PNN | c.102G>C p.P34= | Silent (SNP) | VAF 69/100 reads (69%) | catalogued as rs375209050; called by muse, mutect2, varscan2
- PTPRD | c.783G>T p.G261= | Silent (SNP) | VAF 41/206 reads (20%) | called by muse, mutect2, varscan2
- RGL3 | c.1095G>A p.V365= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV63387211; called by muse, mutect2, varscan2
- SORCS1 | c.660G>A p.L220= | Silent (SNP) | VAF 26/252 reads (10%) | called by muse, mutect2
- TMIGD3 | c.657G>A p.L219= (on ENST00000369717 / NM_001081976.2; = p.L300= on NM_020683.7) | Silent (SNP) | VAF 150/387 reads (39%) | catalogued as rs1434383769; called by muse, mutect2, varscan2
- ZYG11A | c.1935C>T p.L645= | Silent (SNP) | VAF 48/228 reads (21%) | called by muse, mutect2, varscan2
- CEP112 | c.*9G>A | 3'UTR (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- FAM201B | n.566C>T | RNA (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- JPH3 | c.382+789G>T | Intron (SNP) | VAF 3/33 reads (9%) | catalogued as rs1364964728; called by muse, mutect2
- KSR1 | c.986-196G>A | Intron (SNP) | VAF 6/83 reads (7%) | catalogued as rs1242549396; called by muse, mutect2
- MAP4K4 | c.2517+1218C>T | Intron (SNP) | VAF 16/84 reads (19%) | catalogued as rs541836462; called by muse, mutect2, varscan2
- PKP3 | c.2359-105G>A | Intron (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- RNF213 | c.10423+10G>A | Intron (SNP) | VAF 10/27 reads (37%) | catalogued as COSV60401367; called by muse, mutect2, varscan2
- SMC6 | c.1730+1322C>T | Intron (SNP) | VAF 29/176 reads (16%) | called by muse, mutect2, varscan2
